Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BS, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BS-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with right thigh mass; suspect sarcoma.

Specimens Submitted:

- 1: Tru-cut biopsy right thigh sarcoma
- 2: Right thigh sarcoma

DIAGNOSIS:

- 1) THIGH, RIGHT SARCOMA; TRUCUT BIOPSY:
- HIGH GRADE PLEOMORPHIC SARCOMA.
- 2) THIGH, RIGHT SARCOMA; EXCISION:
- UNDIFFERENTIATED HIGH GRADE PLEOMORPHIC SARCOMA (MALIGNANT FIBROUS HISTIOCYTOMA).
- TUMOR MEASURES 19.7 CM GREATEST DIMENSION, INVOLVES FIBROADIPOSE TISSUE AND SKELETAL MUSCLE, SHOWS ABOUT 30% NECROSIS (GROSS ESTIMATE), AND COMES WITHIN 0.03 CM OF UNDESIGNATED INKED MARGIN.
- IMMUNOSTAINS ARE FOCALLY POSITIVE FOR HHF35 AND A MINORITY OF CELLS LABEL FOR SMA AND DESMIN; THERE IS NO STAINING FOR S-100 PROTEIN OR MYOGENIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	AE1:AE3	
	des	
	SMA	
	S-100	
	MYOGENIN	
	CMA (HHF35)	
	IMM RECUT	

** Continued on next page **

ICD-O-3
Sarcoma, pleomorphic, undifferentiated
(8802)3 (8805)3
Code to highest 8805/3
Site (R) thigh NOS C49.2
JW 11/24/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3
NEG CONT

Gross Description:

1). The specimen is received fresh, labeled "Tru-cut biopsy right thigh sarcoma" and consists of multiple core biopsies, measuring 0.6 to 0.8 cm in length x 0.1 cm in diameter. Entirely submitted.

Summary of sections:
FSC- frozen section control
R-remaining tissue

2). The specimen is received fresh, labeled "Right thigh sarcoma " and consists of a piece of skin with attached fibrofatty tissue. The specimen measures 36.2 x 20.7 x 15.3 cm without orientation. The skin measures 20.0 x 3.5 cm. No scar is noted. Specimen is inked black. Serial sectioning reveals a well circumscribed heterogeneous mass, measuring 19.7 x 16.5 x 13.0 cm which is located 0.3 cm from the closest inked margin. Grossly the muscle is not involved by tumor. The cut surface appears white tan and solid with focal microcystic changes. Grossly the mass shows necrosis (30% of the mass) and a hemorrhagic appearance. Representative sections are submitted. TPS and photograph are taken.

Summary of sections:
S skin
TAT- tan solid, mass- medial margin
TM-tumor with inked margin
TMU-tumor with muscle
HEMT-hemorrhagic mass

Summary of Sections:
Part 1: SP: Tru-cut biopsy right thigh sarcoma

Block	Sect.	Site	PCs
1		fsc	1
1		r	1

Part 2: SP: Right thigh sarcoma

Block	Sect.	Site	PCs
8		hemt	8

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGICAL REPORT

----- Page 3 of 3

1	s	1
12	tat	13
5	tm	5
2	tmu	2

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: HIGH GRADE PLEOMORPHIC SARCOMA.
PERMANENT DIAGNOSIS: SAME.

** End of Report **

Criteria	10/29/13	Yes	No
Asynchronous Primary Noted			✓

Source: NCI Genomic Data Commons file 936f6c9d-f48b-49ce-9be5-7d3b4177d67c (TCGA-DX-A8BS.EA9E8A24-BE4D-4526-A3EB-43705F94E3C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).